Surgical pathology report (de-identified scan), TCGA case TCGA-ZG-A9ND, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University Medical Center Hamburg-Eppendorf, specimen TCGA-ZG-A9ND-01A (Primary Tumor).

[page 1 of 2]
Histopathological Report

Date of cancer sample procurement:

Date of pathology report:

Patient ID:

Gross description:

1. (Prostate gland): Prostate gland: Weight: 25 g, Volume: 20 ml, Size: 3 x 3.5 x 4 cm. Adherent seminal vesicles and deferent duct: right side: 3 cm, left side: 2.5 cm. The surface is marked with green ink on the right side, blue ink on the left side. On the right recto-lateral surface a 2.5 x 2.8 cm measuring tissue defect marked with yellow ink. On the left recto-lateral surface a 2.8 x 2.8 cm measuring tissue defect marked with yellow ink. Apical peri-urethral a funnel shaped 1 x 0.8 cm tissue defect marked with red ink. Total of the cross sections: 1.5 cm.
2. (Lymph nodes, right side): 9 x 6.5 x 2 cm measuring adipose tissue containing 14 nodes measuring up to 9 cm.
3. (Lymph nodes, left side): 4.8 x 6 x 2 cm measuring adipose tissue containing 6 nodes measuring up to 6 cm.

Microscopy:

1. Apex right and left: Right 8 tissue blocks, left 8 tissue blocks (total 16 tissue blocks). 3 cross sections: Right 8 tissue blocks, left 8 tissue blocks (total 16 tissue blocks). Basis right and left: Right 6 tissue blocks, left 8 tissue blocks (total 14 tissue blocks). Seminal vesicles right and left: Right 4 tissue blocks, left 4 tissue blocks (total 8 tissue blocks). Deferent ducts right and left: Right 1 tissue block, left 1 tissue block (total 2 tissue blocks).
2. Lymph nodes, right side: 35 tissue blocks.
3. Lymph nodes, left side: 22 tissue blocks.

ICD-O-3
Adenocarcinoma NOS 8140/3
Site: Prostate NOS C61.9
p1123/14

Diagnosis:

1. (Prostate gland): Poorly differentiated prostatic adenocarcinoma, Gleason 5+4=9, (Gleason 5: 80%, Gleason 4: 18%, Gleason 3: 2%). Tumor involves both lobes with the main focus on the right side. Maximum tumor diameter: 33 mm. Tumor infiltration into peri prostatic adipose tissue in 1 tissue blocks (maximum invasion length 0.8 mm, maximal invasion depth 0.7 mm). Negative circumferential and peri-urethral surgical margins.

Remaining prostatic tissue with small foci of prostatic intraepithelial neoplasia (high grade PIN) and signs of myoglandular hyperplasia of the prostate. Urothelium of the prostatic urethra without dysplasia. Tumor-free seminal vesicles and deferent ducts.

2. (Lymph nodes, right side): Five tumor-free lymph nodes (0/5).
3. (Lymph nodes, left side): Three tumor-free lymph nodes (0/3).

[page 2 of 2]
Tumor classification

(in consideration of the intraoperative frozen-section and immunohistochemical analyses):

pT3a, Gleason 5+4=9 (Gleason 5: 70%, Gleason 4: 28%, Gleason 3: 12%), maximum tumor diameter: 33 mm, tumor volume approx. 3.76 ml (Gleason 5: 2.63 ml, Gleason 4: 1.05 ml, Gleason 3: 0.08 ml), pN0 (0/8), L1, V0, R0

Comments:

Tumorinfiltration into peri-prostatic adipose tissue in tissue blocks BR3A.

The preceding intraoperative frozen section showed more adenocarcinoma on both sides with negative surgical margins.

Immunohistochemical analyses of tumor blocks 1E and 1F of the intraoperative frozen section revealed lymphatic invasion but no venous invasion (V0).

Immunohistochemical analyses (AE1/AE3) on two lymph nodes (tissue blocks 2P, 2Q, 2R, 2S, 2T, 2Z and 2AB) did not reveal any metastases.

One macroscopic image for tumor mapping.

Source: NCI Genomic Data Commons file 40c69d40-8b08-47c2-a5d1-0268f8f62316 (TCGA-ZG-A9ND.89122E71-1246-44A5-9D44-4F95284EB02E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).